Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64L, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64L-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A-D. Brain, right frontal mass #1-#4 and CUSA, biopsies: Low-grade oligodendroglioma (WHO grade II). See comment.

Comment: The tumor shows focal high cellularity and increased proliferative activity [up to 3-4 mitoses per 10 HPF and Ki-67 labeling index (up to 10-15%)] suggesting focal early progression. The findings are insufficient for a grade III designation.

Interpreted by:

Report electronically signed by

Transcribed by:

Preliminary Frozen Section Consultation:

A. Brain, right frontal mass #1, smears: Glioma. Hold over for final grading and histiologic typing on permanent sections.

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "right frontal brain mass #1" is a 7.2 x 6.5 x 2.5 cm portion of brain. Smears prepared.

continued next page Page 1 of 2

ICD-O-3
Oligodendroglioma NOS
9460/3
Site @ Brain, frontal lobe
Site Brain, supratentorial NOS
C71.1
C71.0
JW 5/10/13

[page 2 of 2]
Representative sections are submitted. Grossed by

B. Received fresh labeled "right frontal brain mass #2" is a 3.9 x 3.2 x 1.7 cm aggregate of two portions of hemorrhagic brain, 3.2 x 2.1 cm in greatest dimension. Representative sections are submitted. Grossed by

C. Received fresh labeled "right frontal brain mass #3" is a 3.5 x 3.2 x 2.2 cm portion of brain. Representative sections are submitted for permanent sections only. Grossed by

D. Received fresh within a trap labeled "specimen trap - right frontal brain mass #4" is a 7.5 x 5.0 x 1.0 cm aggregate of brain fragments and blood clot. All submitted for permanent sections only. Grossed by

Block Summary:

Part A: Right frontal brain mass

- 1 Rt frontal brain 1
- 2 Rt frontal brain 2
- 3 Rt frontal brain 3
- 4 Rt frontal brain 4

Part B: Right frontal brain mass #2

- 1 Rt frontal brain #2-1
- 2 Rt frontal brain #2-2
- 3 Rt frontal brain #2-3
- 4 Rt frontal brain #2-4
- 5 Rt frontal brain #2-5

Part C: Right frontal brain mass #3

- 1 Rt frontal brain mass #3-1
- 2 Rt frontal brain mass #3-2
- 3 Rt frontal brain mass #3-3
- 4 Rt frontal brain mass #3-4

Part D: Cusa specimen trap - right frontal brain mass

- 1 Cusa specimen 1
- 2 Cusa specimen 2
- 3 Cusa specimen 3
- 4 Cusa specimen 4
- 5 Cusa specimen 5
- 6 Cusa specimen 6
- 7 Cusa specimen 7

END OF REPORT

Page 2 of 2

lw 4/2/13

Source: NCI Genomic Data Commons file 03b41115-a551-458c-a442-f5fc322b3916 (TCGA-DB-A64L.B8075A84-8641-4085-9B51-DF2E1BC37A18.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).